Somatic mutation profile of tumor specimen ALCH-B1LL-TTP1-A (aliquot ALCH-B1LL-TTP1-A-1-0-D-A710-36) from ALCHEMIST case ALCH-B1LL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.6 years (22,485 days).
Specimen ALCH-B1LL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8b23feb-16c3-482b-ae88-4f62b07c1bd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1LL-NB1-A (Blood Derived Normal), aliquot ALCH-B1LL-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38026dd0-199c-4bf4-84a7-2ab763de0a7d

The open-access MAF lists 66 somatic variants for this specimen: 44 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 20, Nonsense Mutation 3, Splice Site 2, RNA 1, Frame Shift Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 120/279 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MET | c.3028+1G>A p.X1010_splice | Splice Site (SNP) | VAF 71/158 reads (45%) | hotspot (GDC flag); catalogued as COSV59256499, COSV59256681, COSV59259384, COSV59260405; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 35/79 reads (44%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ADAMTS4 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs370694866; called by muse, mutect2, varscan2
- AKAP6 | c.5564G>A p.R1855H | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1050582204, COSV55218444; called by muse, mutect2, varscan2
- ARHGAP25 | c.578G>A p.R193Q (on ENST00000409202 / NM_001007231.3; = p.R185Q on NM_014882.3) | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs756769739; called by muse, mutect2
- ARID4A | c.3100G>A p.E1034K | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.98); catalogued as rs751553372; called by muse, mutect2, varscan2
- ASXL1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769717271, COSV60103095, COSV60109115; called by muse, mutect2
- DPPA2 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.778); catalogued as rs199811743; called by mutect2, varscan2
- KIF16B | c.3404G>A p.R1135H | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs766313563; called by muse, mutect2, varscan2
- LRRTM3 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as COSV63671479; called by muse, mutect2, varscan2
- LRTM1 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142542421; called by muse, mutect2
- MDN1 | c.5677G>A p.V1893I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.355); catalogued as rs370208664; called by muse, mutect2, varscan2
- MTMR2 | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 114/233 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1302229712; called by muse, mutect2, varscan2
- OR4K5 | c.495C>A p.N165K | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV100262168; called by muse, mutect2, varscan2
- POLR3A | c.3365T>C p.L1122P | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.886); catalogued as rs769013767; called by muse, mutect2
- PSG7 | c.581A>T p.Q194L | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV101343224; called by muse, mutect2
- XDH | c.2347G>A p.V783I | Missense Mutation (SNP) | VAF 64/351 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.429); catalogued as rs138717520; called by muse, mutect2, varscan2
- BMPER | c.1832G>T p.R611I | Missense Mutation (SNP) | VAF 32/618 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C1R | c.273+7del | Splice Region (DEL) | VAF 53/135 reads (39%) | called by mutect2, pindel, varscan2
- CARTPT | c.293A>T p.K98M | Missense Mutation (SNP) | VAF 86/259 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CEP290 | c.2498G>A p.W833* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | called by muse, varscan2
- DSCAML1 | c.3329T>C p.V1110A (on ENST00000321322; = p.V1050A on NM_020693.4) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPHX2 | c.735+2T>G p.X245_splice | Splice Site (SNP) | VAF 25/117 reads (21%) | called by muse, mutect2, varscan2
- FKBP4 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- GARS1 | c.2057T>G p.L686R | Missense Mutation (SNP) | VAF 51/379 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPC5 | c.495A>T p.R165S | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); called by muse, mutect2
- GRHL2 | c.948C>G p.Y316* | Nonsense Mutation (SNP) | VAF 53/406 reads (13%) | called by muse, mutect2, varscan2
- HMGB3 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2
- JMJD1C | c.7426C>G p.Q2476E | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KYAT3 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- NOVA2 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPAT | c.473C>G p.T158S | Missense Mutation (SNP) | VAF 35/333 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.093); called by muse, mutect2
- OR5K3 | c.329C>A p.T110K | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2
- PIK3CA | c.2710T>A p.Y904N | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRKCG | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, varscan2
- PYDC2 | c.80A>G p.K27R | Missense Mutation (SNP) | VAF 89/203 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RASL10A | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- RTL9 | c.3908G>T p.R1303M | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEC14L1 | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- SFTPA1 | c.211_212del p.G71Kfs*2 | Frame Shift Del (DEL) | VAF 16/106 reads (15%) | called by mutect2, pindel, varscan2
- TIAM1 | c.2821C>G p.P941A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMSB10 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- TTI1 | c.841A>G p.K281E | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- ANKRD12 | c.4317T>C p.S1439= | Silent (SNP) | VAF 10/187 reads (5%) | called by muse, mutect2
- ARHGAP6 | c.45G>T p.S15= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs769819219, COSV61630862; called by muse, mutect2, varscan2
- COL25A1 | c.1143C>A p.P381= | Silent (SNP) | VAF 61/212 reads (29%) | called by muse, mutect2, varscan2
- DEPDC1B | c.138G>A p.A46= | Silent (SNP) | VAF 80/205 reads (39%) | catalogued as rs753975071; called by muse, mutect2, varscan2
- FAM71C | c.234C>T p.P78= | Silent (SNP) | VAF 10/107 reads (9%) | called by muse, mutect2, varscan2
- FREM2 | c.5454C>T p.F1818= | Silent (SNP) | VAF 59/148 reads (40%) | catalogued as rs746646649; called by muse, mutect2, varscan2
- GCH1 | c.294G>A p.A98= | Silent (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- GLIS2 | c.1266G>A p.G422= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- JRK | c.624C>A p.G208= | Silent (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- KPNA2 | c.190C>T p.L64= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs1555703949; called by muse, mutect2, varscan2
- L1CAM | c.363C>A p.G121= | Silent (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- LMNA | c.456C>T p.L152= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV61541944; called by muse, mutect2, varscan2
- LMTK3 | c.15C>A p.G5= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- LPAR6 | c.477T>G p.S159= | Silent (SNP) | VAF 64/147 reads (44%) | called by muse, mutect2, varscan2
- MYH3 | c.3510G>A p.A1170= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs751145040; called by muse, mutect2, varscan2
- NTN4 | c.780C>A p.G260= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- PDZD8 | c.3069G>C p.L1023= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as COSV53691194; called by muse, mutect2, varscan2
- SIMC1 | c.757C>A p.R253= (on ENST00000443967 / NM_001308196.1; = p.R272= on NM_001308195.2) | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV57904129; called by muse, mutect2, varscan2
- SNRPN | c.123C>T p.I41= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV57594867; called by muse, mutect2, varscan2
- USH2A | c.6198C>A p.S2066= | Silent (SNP) | VAF 70/322 reads (22%) | called by muse, varscan2
- ABCA7 | c.498+99C>T | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- LINC02868 | n.176C>A | RNA (SNP) | VAF 20/86 reads (23%) | catalogued as rs1295577667; called by muse, mutect2, varscan2
